Somatic mutation profile of tumor specimen TCGA-A2-A0CU-01A (aliquot TCGA-A2-A0CU-01A-12W-A050-09) from TCGA case TCGA-A2-A0CU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.4 years (26,823 days).
Specimen TCGA-A2-A0CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a76a4e-ee9e-43be-ae99-04cfbfaa6d53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CU-10A (Blood Derived Normal), aliquot TCGA-A2-A0CU-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009ea716-367b-47bb-b755-c2a6cb714bca

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2882C>T p.S961L | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as rs748931549, COSV56851544; called by muse, mutect2, varscan2
- C1orf87 | c.1417A>T p.T473S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV100966920; called by muse, mutect2
- CCDC125 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV101143490; called by muse, mutect2
- CILP | c.1443C>A p.S481R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56024830; called by muse, mutect2, varscan2
- DCAF4L1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs1480842979, COSV60786280, COSV60786538; called by muse, mutect2, varscan2
- DGKG | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.701); catalogued as rs372904433; called by muse, mutect2, varscan2
- EHF | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV57668368; called by muse, mutect2, varscan2
- FCGR2C | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100912502; called by muse, mutect2
- FREM1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs369523355; called by muse, mutect2, varscan2
- GLB1L3 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769500802, COSV66281884; called by muse, mutect2, varscan2
- GNB3 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 21/217 reads (10%) | catalogued as rs782043619, COSV51831196, COSV51834237; called by muse, mutect2, varscan2
- LDB2 | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.047); catalogued as COSV58770927; called by muse, mutect2, varscan2
- NPR2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs746138473, COSV61311923; called by muse, mutect2, varscan2
- OR56A1 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV57362892; called by muse, mutect2, varscan2
- PAGE2 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 47/520 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100892289; called by muse, mutect2
- PARP12 | c.1762G>C p.G588R | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54934792; called by muse, mutect2, varscan2
- PGA5 | c.839C>G p.T280S | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56715847; called by muse, mutect2, varscan2
- PPP1R32 | c.1240A>C p.N414H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58545042; called by muse, mutect2, varscan2
- REV1 | c.3382C>T p.L1128= | Splice Region (SNP) | VAF 21/107 reads (20%) | catalogued as COSV51484060, COSV51486006; called by muse, mutect2, varscan2
- SNX25 | c.1975-2A>T p.X659_splice | Splice Site (SNP) | VAF 42/224 reads (19%) | catalogued as COSV99252353; called by muse, mutect2, varscan2
- SPNS1 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV57955017; called by muse, mutect2, varscan2
- SRCAP | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as COSV52673774; called by muse, mutect2, varscan2
- WIF1 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV54132391; called by muse, mutect2, varscan2
- WIF1 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99682574; called by muse, mutect2, varscan2
- YIPF7 | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100274389, COSV60657099; called by muse, mutect2, varscan2
- IRF2BP2 | c.1345dup p.S449Ffs*7 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- NEXMIF | c.1091del p.F364Sfs*6 | Frame Shift Del (DEL) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- NRBP1 | c.430del p.A144Pfs*15 | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | called by mutect2, pindel, varscan2
- CABIN1 | c.1128G>A p.G376= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99572703; called by muse, mutect2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- HUWE1 | c.3096T>C p.S1032= | Silent (SNP) | VAF 21/353 reads (6%) | catalogued as COSV99470607; called by muse, mutect2
- KDM4C | c.84G>A p.E28= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV67187317; called by muse, mutect2, varscan2
- MRPL17 | c.468C>T p.L156= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs781757787, COSV99996775; called by muse, mutect2
- PDE6C | c.486C>T p.S162= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV65117392; called by muse, mutect2
- PTK2 | c.1968G>A p.T656= | Silent (SNP) | VAF 20/311 reads (6%) | catalogued as rs776101894, COSV100569374; called by muse, mutect2
- SOCS7 | c.1275C>T p.P425= | Silent (SNP) | VAF 46/131 reads (35%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.1056T>A p.A352= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV60292641; called by muse, mutect2, varscan2
- WWC3 | c.336G>A p.Q112= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs778647252, COSV101081038; called by muse, mutect2
- ZNF486 | c.387G>T p.V129= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs112152275, COSV58719525; called by muse, mutect2, varscan2
- ZNF623 | c.1350G>A p.Q450= | Silent (SNP) | VAF 22/383 reads (6%) | catalogued as COSV101513475, COSV71697222; called by muse, mutect2
- MUC2 | chr11:1099446 T>A | 5'Flank (SNP) | VAF 26/74 reads (35%) | catalogued as rs56290335; called by mutect2, varscan2
